Somatic mutation profile of tumor specimen 0DR6YH from CCDI case PBCGDG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 18.5 years (6,744 days).
Specimen 0DR6YH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b9b951c-5a46-46bc-b72a-a503e046dd28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR6Y7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c741d467-c5d2-4583-8ca5-3e61f3f5ec85

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Intron 2, Frame Shift Ins 1, 5'UTR 1, Translation Start Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 84/402 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 371/747 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519747, COSV52679619, COSV52753659, COSV52782945; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.4786A>G p.M1596V | Missense Mutation (SNP) | VAF 146/699 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64872190; called by muse, mutect2, varscan2
- DNAH5 | c.7958C>T p.T2653I | Missense Mutation (SNP) | VAF 61/564 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs1160211865; called by muse, mutect2, varscan2
- DNAH6 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 79/880 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs946140303; called by muse, mutect2
- FBXL16 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 57/582 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs141455262; called by muse, mutect2
- HIRA | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 28/487 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs781971961, COSV54273169; called by muse, mutect2
- HYAL3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 89/874 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782659618; called by muse, mutect2
- MAGEA12 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 168/810 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.208); catalogued as COSV63294762; called by muse, varscan2
- MED13 | c.6351C>G p.H2117Q | Missense Mutation (SNP) | VAF 124/460 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as rs1253743619, COSV101181033; called by muse, mutect2, varscan2
- PERM1 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 120/481 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.214); catalogued as rs1476333683; called by muse, mutect2, varscan2
- RPA4 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 45/435 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV61264023; called by muse, mutect2, varscan2
- SULT1C2 | c.698T>C p.M233T | Missense Mutation (SNP) | VAF 191/737 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563878077; called by muse, mutect2, varscan2
- ALG5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 81/386 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, varscan2
- CT47A6 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 42/673 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2
- DLG3 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 238/898 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- FRMD7 | c.2020A>G p.M674V | Missense Mutation (SNP) | VAF 72/645 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL18 | c.881A>G p.E294G | Missense Mutation (SNP) | VAF 28/1015 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10D3 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 56/779 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2
- PLEC | c.2400_2403dup p.L802Gfs*84 (on ENST00000322810 / NM_201380.4; = p.L692Gfs*84 on NM_000445.5) | Frame Shift Ins (INS) | VAF 111/540 reads (21%) | called by mutect2, pindel, varscan2
- THSD7B | c.3082A>C p.K1028Q | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2
- USP12 | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF157 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- ZNF598 | c.2507A>G p.N836S | Missense Mutation (SNP) | VAF 160/749 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL6A3 | c.4860T>C p.P1620= | Silent (SNP) | VAF 76/667 reads (11%) | called by muse, mutect2, varscan2
- DACH1 | c.1428A>T p.P476= (on ENST00000619232 / NM_001366712.1; = p.P424= on NM_080759.6) | Silent (SNP) | VAF 23/499 reads (5%) | catalogued as rs1342300758; called by muse, mutect2
- FLNA | c.2451C>T p.P817= | Silent (SNP) | VAF 158/1302 reads (12%) | catalogued as rs782192587, COSV61036565; ClinVar: benign; called by muse, mutect2, varscan2
- HCFC1 | c.3975C>T p.H1325= | Silent (SNP) | VAF 62/607 reads (10%) | catalogued as rs373289538; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGSF1 | c.3261T>C p.C1087= | Silent (SNP) | VAF 244/1010 reads (24%) | called by muse, mutect2, varscan2
- IRS4 | c.2643C>T p.P881= | Silent (SNP) | VAF 192/738 reads (26%) | called by muse, mutect2, varscan2
- KRT18 | c.924C>T p.I308= | Silent (SNP) | VAF 115/436 reads (26%) | catalogued as rs149270992; called by muse, mutect2, varscan2
- PDCD1 | c.711C>G p.P237= | Silent (SNP) | VAF 20/745 reads (3%) | called by muse, mutect2
- TENM1 | c.585G>A p.P195= | Silent (SNP) | VAF 192/853 reads (23%) | catalogued as rs904679942, COSV100950018; called by muse, mutect2, varscan2
- TNFRSF25 | c.972G>A p.S324= | Silent (SNP) | VAF 149/539 reads (28%) | called by muse, mutect2, varscan2
- CRYBG2 | c.4454+13G>A | Intron (SNP) | VAF 27/454 reads (6%) | called by muse, mutect2
- NAALADL2 | c.939+64A>G | Intron (SNP) | VAF 71/273 reads (26%) | called by muse, mutect2, varscan2
- NXF1 | c.-48C>G | 5'UTR (SNP) | VAF 67/370 reads (18%) | called by muse, mutect2, varscan2
- SLC5A5 | c.*16C>T | 3'UTR (SNP) | VAF 218/892 reads (24%) | catalogued as rs367906323; called by muse, mutect2, varscan2
